Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GS, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GS-06A (Metastatic).

ICD 0-3

Melanoma, malignant NOS
8724/3

Site: Inguinal lymph node
C77.4

QD 4/4/13

DIAGNOSIS

- (A) LEFT INGUINAL LYMPH NODE, LYMPHADENECTOMY:
MELANOMA, METASTATIC TO ONE OF ONE LYMPH NODES (1 /1)
Tumor size: 30.0 x 18.0 mm. (per gross measurement)
Location: Intraparenchymal and subcapsular
Extracapsular extension: present

GROSS DESCRIPTION

- (A) "LEFT INGUINAL LYMPH NODE WITH METASTATIC MELANOMA STERILE FOR TIL AND PAN MEL STAINING" – A previously opened tan-gray neoplastic node measuring 3.0 x 1.8 x 1.2 cm. Tumor is submitted for the TIL extraction. No other mass or lymph nodes are visualized. The lymph node has gray to black neoplastic infiltrates which practically replace the entire node. Entirely submitted.

SECTION CODE: A1-A3, one lymph node with neoplastic infiltrates; A4, A5, remaining tissue.

CLINICAL HISTORY

None given.

SNOMED CODES

M-87206

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

/ Medicine

Source: NCI Genomic Data Commons file 8a1513c0-5fcf-418e-ba61-56fb64744b8a (TCGA-D3-A5GS.484DBEA9-8D08-4D24-823A-675F5071204D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).